Somatic mutation profile of tumor specimen 0DUQYW from CCDI case PBCLMN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 1.1 years (417 days).
Specimen 0DUQYW: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff6217c0-1489-4016-8ebb-ec2432e71f10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUR03 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eedbc236-3925-4251-ad90-7a80f94eaa00

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, 5'UTR 3, Intron 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALDH5A1 | c.1424C>A p.P475Q | Missense Mutation (SNP) | VAF 83/406 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as COSV62374398; called by muse, mutect2, varscan2
- ARHGEF11 | c.3727G>A p.V1243I | Missense Mutation (SNP) | VAF 49/387 reads (13%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs111558417, COSV59354403; called by muse, mutect2, varscan2
- BRD4 | c.2828C>T p.P943L | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.011); catalogued as rs753396296; called by muse, mutect2
- BRD8 | c.3481C>T p.R1161W | Missense Mutation (SNP) | VAF 86/377 reads (23%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.876); catalogued as rs780263380; called by muse, mutect2, varscan2
- FAM171A1 | c.2305G>A p.V769I | Missense Mutation (SNP) | VAF 122/212 reads (58%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs1425442305, COSV65315873; called by muse, mutect2, varscan2
- FCRL3 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 41/375 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.349); catalogued as COSV100943377; called by muse, mutect2, varscan2
- MILR1 | c.518A>G p.K173R | Missense Mutation (SNP) | VAF 196/850 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs1012561459; called by muse, varscan2
- ADAMTS1 | c.139T>G p.S47A | Missense Mutation (SNP) | VAF 156/309 reads (50%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOLC1 | c.1502C>A p.A501E | Missense Mutation (SNP) | VAF 50/356 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- PPP4R3C | c.329C>G p.T110R | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); called by muse, mutect2
- SLC8A3 | c.973C>A p.Q325K | Missense Mutation (SNP) | VAF 50/425 reads (12%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TARS3 | c.1997T>A p.V666E | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- TMPRSS11B | c.1171T>C p.C391R | Missense Mutation (SNP) | VAF 158/350 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ZNF316 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 144/302 reads (48%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- ZSCAN4 | c.526C>A p.Q176K | Missense Mutation (SNP) | VAF 16/555 reads (3%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- ACO1 | c.2391C>G p.A797= | Silent (SNP) | VAF 158/347 reads (46%) | catalogued as rs776083510, COSV59378903; called by muse, mutect2, varscan2
- HMCN1 | c.11778C>A p.P3926= | Silent (SNP) | VAF 60/540 reads (11%) | called by muse, mutect2, varscan2
- FGB | c.115-60T>C | Intron (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- GRIK3 | c.-43C>T | 5'UTR (SNP) | VAF 29/121 reads (24%) | called by muse, mutect2, varscan2
- PMPCB | c.99+15A>G | Intron (SNP) | VAF 41/157 reads (26%) | called by muse, mutect2, varscan2
- SPATA13 | c.-222-25946G>A | Intron (SNP) | VAF 13/314 reads (4%) | catalogued as rs1356456652; called by muse, mutect2
- SRRM5 | c.-8C>T | 5'UTR (SNP) | VAF 19/166 reads (11%) | catalogued as rs866864503, COSV56193189; called by muse, mutect2
- ST6GAL1 | c.-18C>T | 5'UTR (SNP) | VAF 38/174 reads (22%) | catalogued as rs1293470833; called by muse, varscan2
